Somatic mutation profile of tumor specimen TCGA-KK-A7AQ-01A (aliquot TCGA-KK-A7AQ-01A-11D-A33T-08) from TCGA case TCGA-KK-A7AQ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.2 years (22,731 days).
Specimen TCGA-KK-A7AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d0f68a0-4f33-4db7-ad3f-0dd78f3dc53a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7AQ-11A (Solid Tissue Normal), aliquot TCGA-KK-A7AQ-11A-11D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d93260f-da2d-4736-a7b8-6f848583f5d3

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 42/117 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATAD5 | c.3434G>A p.C1145Y | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100429952; called by muse, mutect2
- CALCR | c.682G>A p.V228M (on ENST00000649521 / NM_001164737.2; = p.V212M on NM_001742.4) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761921361, COSV100810538, COSV64006457; called by muse, mutect2, varscan2
- DCXR | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs759402588, COSV100178847; called by muse, varscan2
- FBXL17 | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100671354; called by muse, mutect2, varscan2
- FSIP2 | c.20134T>A p.F6712I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs928129379, COSV58085601; called by muse, mutect2, varscan2
- GFI1B | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537470322, COSV59745994; called by muse, mutect2, varscan2
- KIF5A | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV99672958; called by muse, mutect2, varscan2
- KIRREL1 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.146); catalogued as rs372675836; called by muse, mutect2, varscan2
- MKI67 | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100896522; called by muse, mutect2, varscan2
- MYH15 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99843265; called by muse, mutect2, varscan2
- MYO9A | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100613501; called by muse, mutect2, varscan2
- OR13C4 | c.953A>T p.Q318L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV99470154; called by muse, mutect2, varscan2
- PRICKLE2 | c.2293T>G p.S765A (on ENST00000295902; = p.S709A on NM_198859.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99897221; called by muse, mutect2, varscan2
- RABL6 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374394708; called by muse, mutect2, varscan2
- RFX6 | c.1222T>C p.S408P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100263739; called by muse, mutect2
- SERPINB8 | c.1070T>G p.I357S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99729175; called by muse, mutect2, varscan2
- TGFB2 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV65108301; called by muse, mutect2
- TIMM22 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100508195; called by muse, varscan2
- TLR4 | c.389A>C p.K130T (on ENST00000355622 / NM_138554.5; = p.K90T on NM_003266.4) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV100790644; called by muse, mutect2, varscan2
- TTN | c.39813T>A p.H13271Q (on ENST00000591111; = p.H5847Q on NM_003319.4) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | PolyPhen possibly damaging (0.59); catalogued as rs762830792, COSV100612365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZSCAN21 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs761311588, COSV99460929; called by muse, mutect2, varscan2
- ABCD3 | c.705C>A p.A235= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV100238897; called by muse, mutect2, varscan2
- NEO1 | c.1389A>C p.A463= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV99982027; called by muse, mutect2, varscan2
- TMEFF2 | c.633A>G p.A211= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV55834149; called by muse, mutect2, varscan2
- ZDBF2 | c.6684G>A p.S2228= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs769931510, COSV100985602, COSV65624129; called by muse, mutect2, varscan2
- VPS26C | chr21:37221346 C>T | 3'Flank (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2
